Somatic mutation profile of tumor specimen TCGA-23-2079-01A (aliquot TCGA-23-2079-01A-01W-0722-08) from TCGA case TCGA-23-2079, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 46.9 years (17,122 days).
Specimen TCGA-23-2079-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0fb04035-9939-4d02-a601-2c5d0930353e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-2079-10A (Blood Derived Normal), aliquot TCGA-23-2079-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f26729c6-cd6c-4989-93b2-2e156f14ae4b

The open-access MAF lists 65 somatic variants for this specimen: 51 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 13, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 12/15 reads (80%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA7 | c.459G>A p.M153I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54033953; called by muse, mutect2, varscan2
- ARHGAP36 | c.760G>A p.V254M | Missense Mutation (SNP) | VAF 131/383 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV52269709, COSV99358163; called by muse, mutect2, varscan2
- ATP13A4 | c.557C>G p.T186S | Missense Mutation (SNP) | VAF 97/1131 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV99794581, COSV99795295; called by muse, mutect2
- ATP8A1 | c.1685C>G p.T562S | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.363); catalogued as COSV100046309; called by muse, mutect2, varscan2
- BPIFA3 | c.105C>A p.D35E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV64926084; called by muse, mutect2, varscan2
- C11orf53 | c.470A>C p.D157A | Missense Mutation (SNP) | VAF 13/173 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99724778; called by muse, mutect2
- C12orf40 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as COSV61135555; called by muse, mutect2, varscan2
- CACNA1C | c.6119T>C p.V2040A (on ENST00000399634 / NM_001167625.1; = p.V1969A on NM_000719.7) | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.021); catalogued as rs1298514198, COSV59749844; called by muse, mutect2, varscan2
- CAD | c.2032-2A>T p.X678_splice | Splice Site (SNP) | VAF 15/212 reads (7%) | catalogued as COSV99255127; called by muse, mutect2
- CC2D2A | c.3287A>C p.Q1096P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV67504893; called by muse, mutect2, varscan2
- CENPO | c.152A>T p.K51M | Missense Mutation (SNP) | VAF 144/613 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV53231633; called by muse, mutect2, varscan2
- DAPK2 | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs200773863, COSV99977446; called by muse, mutect2, varscan2
- DDX42 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.09); catalogued as COSV63790809; called by muse, mutect2, varscan2
- FAM47A | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 67/100 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs764123221, COSV60495125; called by muse, mutect2, varscan2
- GRIA4 | c.95T>C p.L32P | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56909854; called by muse, mutect2, varscan2
- GTF3C1 | c.3152-2A>T p.X1051_splice | Splice Site (SNP) | VAF 8/22 reads (36%) | catalogued as COSV62243223; called by muse, mutect2, varscan2
- HSF1 | c.441G>A p.M147I | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as rs781788240, COSV101275165; called by muse, mutect2, varscan2
- IAPP | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV99557073; called by muse, varscan2
- IGFN1 | c.1265G>A p.R422K (on ENST00000295591 / NM_001367841.1; = p.R2879K on NM_001164586.2) | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55179359; called by muse, mutect2, varscan2
- KCNN2 | c.1181C>T p.A394V (on ENST00000264773; = p.A606V on NM_021614.4) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV53294735; called by muse, mutect2, varscan2
- LPO | c.888G>T p.Q296H | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51861040, COSV51861292; called by muse, mutect2, varscan2
- MROH2B | c.2159G>C p.R720T | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV68187249; called by muse, mutect2, varscan2
- MYLK2 | c.1131T>A p.H377Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV65659602; called by muse, mutect2, varscan2
- NEK1 | c.2253A>T p.K751N | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV71457422; called by muse, mutect2, varscan2
- NOD1 | c.1352A>T p.E451V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99768112; called by muse, mutect2, varscan2
- OR2M5 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.828); catalogued as COSV100822824; called by muse, mutect2
- OSBPL11 | c.1214T>G p.F405C | Missense Mutation (SNP) | VAF 64/333 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56175471; called by muse, mutect2, varscan2
- PARN | c.1879A>T p.N627Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.017); catalogued as COSV58368869; called by muse, mutect2, varscan2
- PCDHGA3 | c.2096C>T p.A699V | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.012); catalogued as COSV53995177; called by muse, mutect2, varscan2
- PPP2R3A | c.1687C>A p.P563T | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV53868025; called by muse, mutect2, varscan2
- PTPRF | c.5161G>C p.E1721Q | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63443031, COSV63447137; called by muse, mutect2, varscan2
- RIMS2 | c.2030C>G p.P677R (on ENST00000666250 / NM_001348490.2; = p.P485R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51704495; called by muse, mutect2, varscan2
- RNF157 | c.1442A>C p.N481T | Missense Mutation (SNP) | VAF 84/116 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); catalogued as rs553918046, COSV53946878; called by muse, mutect2
- RNF20 | c.2445C>A p.N815K | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV66661889; called by muse, mutect2, varscan2
- SALL2 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 20/58 reads (34%) | catalogued as COSV58104858; called by muse, mutect2, varscan2
- SETD2 | c.7602G>C p.E2534D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as rs1248081279, COSV100339081, COSV57433904, COSV57445535; called by muse, mutect2, varscan2
- SLC22A14 | c.306G>C p.W102C | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99070257, COSV99828257; called by muse, mutect2
- SRP68 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.058); catalogued as COSV57161367, COSV57163880; called by muse, mutect2, varscan2
- STMN2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV55221171, COSV99627078; called by muse, mutect2, varscan2
- TASOR | c.3452T>A p.L1151* (on ENST00000355628 / NM_001365636.2; = p.L775* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV62928907; called by muse, mutect2, varscan2
- TTC5 | c.1208A>T p.Y403F | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51871721; called by muse, mutect2, varscan2
- TUBB4A | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 150/409 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.964); catalogued as COSV51161099; called by muse, mutect2, varscan2
- TULP4 | c.1330A>G p.M444V | Missense Mutation (SNP) | VAF 48/154 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs376271444, COSV100893531; called by muse, mutect2, varscan2
- UGT3A1 | c.800A>G p.Y267C | Missense Mutation (SNP) | VAF 138/250 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV57100848; called by muse, mutect2, varscan2
- WHRN | c.2653G>T p.A885S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54333143; called by muse, mutect2, varscan2
- XPO4 | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs749138831, COSV55010772, COSV55011441; called by muse, mutect2, varscan2
- ZNF654 | c.2867T>G p.I956R | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100525780; called by muse, mutect2
- CACNB4 | c.87_109del p.R30Wfs*24 | Frame Shift Del (DEL) | VAF 45/147 reads (31%) | called by mutect2, pindel, varscan2
- JAM2 | c.586del p.T196Lfs*37 | Frame Shift Del (DEL) | VAF 61/275 reads (22%) | called by mutect2, pindel, varscan2
- NFIC | c.1520del p.L507Rfs*36 (on ENST00000443272 / NM_001245002.2; = p.L427Rfs*36 on NM_005597.4) | Frame Shift Del (DEL) | VAF 92/286 reads (32%) | called by mutect2, pindel, varscan2
- ABL2 | c.288C>T p.S96= (on ENST00000502732 / NM_007314.4; = p.S81= on NM_005158.5) | Silent (SNP) | VAF 41/169 reads (24%) | catalogued as COSV100772765; called by muse, mutect2, varscan2
- CEP350 | c.9246G>A p.L3082= | Silent (SNP) | VAF 51/168 reads (30%) | catalogued as COSV62607035; called by muse, mutect2, varscan2
- CHD7 | c.3237C>T p.A1079= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV101418293, COSV71111978; called by muse, mutect2, varscan2
- CNTNAP5 | c.2211C>T p.C737= | Silent (SNP) | VAF 234/638 reads (37%) | catalogued as rs781721386, COSV70486451; called by muse, varscan2
- CRIP3 | c.390C>T p.P130= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs760463930, COSV99240373; called by muse, mutect2
- CST6 | c.265C>T p.L89= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1301858803, COSV56412360; called by muse, mutect2, varscan2
- HLA-E | c.1062G>A p.E354= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV64927719; called by muse, mutect2, varscan2
- PMM2 | c.168G>A p.L56= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs1013771553, COSV51633380; called by muse, mutect2, varscan2
- RIMBP2 | c.1293C>A p.I431= | Silent (SNP) | VAF 45/51 reads (88%) | catalogued as COSV55464101, COSV55479457; called by muse, mutect2, varscan2
- SEC14L1 | c.2112C>T p.S704= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV101171054; called by muse, mutect2, varscan2
- TENM3 | c.465C>A p.L155= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV101305155; called by muse, mutect2
- TSPYL5 | c.693G>C p.G231= | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as COSV59072188; called by muse, mutect2, varscan2
- TUBE1 | c.705G>A p.K235= | Silent (SNP) | VAF 89/296 reads (30%) | catalogued as COSV64088045; called by muse, mutect2, varscan2
- THRB | c.284-12781G>A | Intron (SNP) | VAF 78/236 reads (33%) | catalogued as rs773045868, COSV99769510; called by muse, mutect2, varscan2
